Gene-level copy-number profile of tumor specimen TCGA-UC-A7PG-06A from TCGA case TCGA-UC-A7PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 44.4 years (16,231 days).
Specimen TCGA-UC-A7PG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.caf81b43-15ba-4755-a146-ae86ee8fbca9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UC-A7PG-11C (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d792aca1-3ff6-4c17-ad62-4a98638e2b55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 445; copy number 2: 26,691; copy number 3: 22,279; copy number 4: 9,907; copy number 5: 402; copy number 6: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UC-A7PG-06A-11D-A42N-01): tumor purity 0.65, ploidy 2.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,797,047–151,828,488, 2 genes (within-gene range 0–4): AC068647.2, AADAC.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 421 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:79,967,733–89,207,040, 130 genes, copy number 5 (broad region; genes not listed).
- chr1:95,937,901–99,244,794, 31 genes, copy number 5 (within-gene range 4–11): LINC02790, RNU1-130P, LINC01787, AC092393.1, UBE2WP1, EEF1A1P11, RN7SL831P, NDUFS5P2, RPL7P9, RN7SKP270, PTBP2, DPYD, DPYD-AS1, DPYD-IT1, SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1.
- chr1:185,558,371–186,681,446, 19 genes, copy number 6 (within-gene range 4–6): LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR.
- chr1:195,747,024–197,775,696, 26 genes, copy number 5 (within-gene range 4–5): AL353709.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1.
- chr1:215,005,775–216,423,448, 10 genes, copy number 5: KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1.
- chr3:145,523,538–146,544,856, 15 genes, copy number 5 (within-gene range 4–5): LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1.
- chr3:146,909,685–151,761,339, 104 genes, copy number 5 (broad region; genes not listed).
- chr3:151,759,747–151,784,894, 2 genes, copy number 5: AC068647.1, AADACP1.
- chr13:19,026,001–19,032,626, 2 genes, copy number 5 (within-gene range 2–5): GTF2IP3, AL137001.1.
- chr14:18,333,726–19,936,757, 82 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 445. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
